Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A4DV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A4DV-01A (Primary Tumor).

[page 1 of 2]
H/PA Discrepancy	Yes	No

ANATOMIC PATHOLOGY REPORT

UUID: ASD9C1B2-9F81-42BD-927B-F6FC22F38F62

ICD-O-3

Oligodendroglioma, III 9451/3

CQCF Site: supratentorial brain, NOS C71.0

Path: frontal lobe C71.1 W 9/25/12

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Left frontal tumor, FS
2. Left frontal tumor, FS
3. Left frontal tumor, perm

CLINICAL DIAGNOSIS:

Tumor

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name are multiple irregular tan-white and hemorrhagic soft tissue fragments, 1.2 x 0.7 x 0.4 cm. A smear preparation is prepared and examined. The specimen is submitted in its entirety for frozen section on one chuck with residual permanent submitted in cassette F2A.

FROZEN SECTION DIAGNOSIS:

CONSISTENT WITH DIFFUSE GLIOMA, FAVOR OLIGODENDROGLIOMA.

2. Received fresh for frozen section labeled with the patient's name and "left frontal tumor" consists of multiple irregular tan-white hemorrhagic soft tissue fragments aggregating to 0.6 x 0.2 x 0.1 cm. A smear preparation is prepared and examined. The specimen is submitted in its entirety for frozen section on one chuck with residual permanent submitted in cassette F2A.

FROZEN SECTION DIAGNOSIS:

CONSISTENT WITH INFILTRATING GLIOMA.

3. Received in formalin labeled with the patient's name and "left frontal tumor" consists of multiple irregular tan-white hemorrhagic soft tissue fragments aggregating to 2.4 x 1.5 x 1.2 cm. The tissues are sectioned and totally submitted in cassettes 3A-C.

MICROSCOPIC DESCRIPTION:

1-3. Sections demonstrate a diffusely infiltrative glial neoplasm involved in both the gray and white matter. The tumor cells demonstrate only mild to moderate cytologic atypia with consistent round nuclei and prominent perinuclear halos. In some areas, mitotic figures are rare but in other areas up to 12 mitoses are seen per 10 high power fields. Microvascular proliferation is not seen and there is no necrosis.

[page 2 of 2]
ANATOMIC PATHOLOGY REPORT
PERMANENT CHART COPY
(Chart in Op

NEUROPATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

Numerous MIB-1 reactive cells are present throughout the tumor. A labeling index of 7.0% is calculated.

DIAGNOSIS:

- 1-3. LEFT FRONTAL TUMOR, BIOPSY AND RESECTION:
ANAPLASTIC OLIGODENDROGLIOMA, GRADE III
- MIB-1 LABELING INDEX = 7.0%

CPT:

Dictated by:
Verified by:

Source: NCI Genomic Data Commons file 1bf8f86c-2a58-428e-8945-789bf663fe64 (TCGA-HT-A4DV.A5D9C1B2-9F81-42BD-927B-F6FC22F38F62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).